TCGA case TCGA-69-7973 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - Cleveland Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dc9eaaa0-0bfd-46d0-994f-310826879da4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.2; Tissue or organ of origin: Middle lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 42.0 years (15,355 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel; Days to treatment start: 63 days; Days to treatment end: 63 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 91 days; Days to treatment end: 132 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 230 days; Disease response: Tumor Free.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 25; Tobacco smoking quit year: 2011.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-69-7973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-69-7973-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample TCGA-69-7973-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-69-7973-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Middle; Location lung parenchyma: Central Lung; EGFR mutation status: Yes; Pulmonary function test indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxotere.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Treatment outcome at TCGA followup: Complete Remission/Response; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 230 days; disease-specific survival: no event (censored), 230 days; disease-free interval: no event (censored), 230 days; progression-free interval: no event (censored), 230 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-69-7973-01A-11D-2183-01): tumor purity 0.55, ploidy 3.35, whole-genome doublings 1.
